Somatic mutation profile of tumor specimen TCGA-59-2351-01A (aliquot TCGA-59-2351-01A-01W-0799-08) from TCGA case TCGA-59-2351, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-59-2351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0748d77-9278-487b-b401-650f0842b63c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2351-10A (Blood Derived Normal), aliquot TCGA-59-2351-10A-01W-0800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bece3a44-a19b-4eb1-8518-1621388946e8

The open-access MAF lists 114 somatic variants for this specimen: 86 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 26, Splice Site 7, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.3639T>A p.S1213R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50733550, COSV50807155; called by muse, mutect2, varscan2
- AFF2 | c.2539C>G p.P847A | Missense Mutation (SNP) | VAF 5/154 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99663229; called by muse, mutect2
- AHNAK2 | c.6614C>A p.P2205H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV60908959; called by muse, mutect2, varscan2
- AIFM1 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54852822; called by muse, mutect2, varscan2
- AMER2 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63436410; called by muse, mutect2, varscan2
- ATAD2 | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54877874; called by muse, mutect2, varscan2
- AZGP1 | c.461G>C p.W154S | Missense Mutation (SNP) | VAF 119/707 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52797108; called by muse, mutect2, varscan2
- BCL2L12 | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV99881021; called by muse, mutect2, varscan2
- BLM | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61922175, COSV61926395; called by muse, mutect2
- CCDC174 | c.1339C>G p.Q447E | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99513721; called by muse, mutect2, varscan2
- CCDC8 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781188062, COSV56772418; called by muse, mutect2, varscan2
- CDAN1 | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.12); catalogued as COSV51899469; called by muse, mutect2, varscan2
- CDH24 | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99399437; called by mutect2, varscan2
- CDK12 | c.2923A>G p.K975E | Missense Mutation (SNP) | VAF 193/335 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV70999480; called by muse, mutect2, varscan2
- CIC | c.1281G>C p.Q427H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.809); catalogued as rs757465509, COSV50548523; called by muse, varscan2
- COL5A3 | c.2658+1G>T p.X886_splice | Splice Site (SNP) | VAF 32/113 reads (28%) | catalogued as COSV53406888; called by muse, mutect2, varscan2
- DEPDC7 | c.1501C>A p.H501N (on ENST00000241051 / NM_001077242.2; = p.H492N on NM_139160.2) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53805951; called by muse, mutect2, varscan2
- DMXL2 | c.1746G>C p.E582D | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51841490; called by muse, mutect2, varscan2
- DNA2 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV63063088; called by muse, mutect2, varscan2
- EDC3 | c.165-2A>G p.X55_splice | Splice Site (SNP) | VAF 28/137 reads (20%) | catalogued as COSV100166095, COSV59339273; called by muse, mutect2, varscan2
- EIF2B5 | c.1936C>T p.R646C (on ENST00000647909; = p.R638C on NM_003907.3) | Missense Mutation (SNP) | VAF 77/267 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs541227484, COSV56603790; called by muse, mutect2, varscan2
- ERN2 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs754261303, COSV56831870, COSV56835403; called by muse, mutect2, varscan2
- FAT1 | c.10518G>T p.K3506N | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV71672200; called by muse, mutect2, varscan2
- FBN3 | c.7343A>G p.D2448G | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54454497; called by muse, mutect2, varscan2
- FLG2 | c.4400C>T p.T1467I | Missense Mutation (SNP) | VAF 304/1921 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV66166932; called by muse, mutect2, varscan2
- FREM2 | c.7637T>G p.M2546R | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV99748292; called by muse, mutect2
- FYB1 | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 83/494 reads (17%) | catalogued as COSV60941688, COSV60955472; called by muse, mutect2, varscan2
- GALNT8 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 89/249 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV52895028; called by muse, mutect2, varscan2
- GANAB | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 100/561 reads (18%) | catalogued as COSV60462425; called by muse, mutect2, varscan2
- HEATR1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV63979936; called by muse, mutect2, varscan2
- HMCN1 | c.5990C>G p.A1997G | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54880896; called by muse, mutect2, varscan2
- INPP5D | c.3127C>A p.P1043T (on ENST00000445964 / NM_001017915.3; = p.P1042T on NM_005541.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV64035684; called by muse, mutect2, varscan2
- INTS6L | c.1629A>T p.E543D | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100878074; called by muse, mutect2, varscan2
- IQGAP1 | c.3932A>G p.D1311G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV51582005; called by muse, mutect2, varscan2
- JMJD1C | c.5276+1G>T p.X1759_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV59513175; called by muse, varscan2
- KCNS3 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58405558; called by muse, mutect2, varscan2
- KRT6B | c.995G>C p.S332T | Missense Mutation (SNP) | VAF 208/1240 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV52882227, COSV52884561, COSV52885054; called by muse, mutect2, varscan2
- LRIT2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1322718191, COSV64518128; called by muse, mutect2, varscan2
- LRP2 | c.10235C>A p.A3412D | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55543030; called by muse, mutect2, varscan2
- LRRC49 | c.1593+1G>A p.X531_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV53008347; called by muse, mutect2, varscan2
- MAP2 | c.59C>A p.T20K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV52282756, COSV99560059; called by muse, mutect2, varscan2
- MAP2K6 | c.488T>G p.V163G | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63005182; called by muse, mutect2, varscan2
- MCTP1 | c.1645A>C p.I549L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV56505752; called by muse, mutect2, varscan2
- MDN1 | c.7861G>C p.D2621H | Missense Mutation (SNP) | VAF 98/665 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as rs377084929, COSV65517935; called by muse, mutect2, varscan2
- MUC16 | c.5087C>G p.S1696* | Nonsense Mutation (SNP) | VAF 188/860 reads (22%) | catalogued as COSV67448393; called by muse, mutect2, varscan2
- MYLK | c.1499G>A p.W500* | Nonsense Mutation (SNP) | VAF 81/258 reads (31%) | catalogued as COSV60605516; called by muse, mutect2, varscan2
- NBEAL2 | c.6831C>G p.H2277Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99435593; called by muse, mutect2, varscan2
- NCK2 | c.950C>G p.P317R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99255586; called by muse, mutect2
- PEAK1 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV56931592; called by muse, mutect2, varscan2
- PPP1R12A | c.1937C>G p.T646R | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV54105803; called by muse, mutect2, varscan2
- PROM1 | c.2174A>G p.N725S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as COSV71699170; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.547C>A p.P183T (on ENST00000421990 / NM_001136042.2; = p.P165T on NM_025267.3) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100799246; called by muse, mutect2
- RBM41 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 13/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99179779; called by muse, mutect2
- RBP5 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 123/357 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1163577532, COSV99866834; called by muse, mutect2, varscan2
- RBPJL | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs139100496, COSV100636973; called by muse, mutect2, varscan2
- REV3L | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 78/141 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533806331, COSV62615884, COSV62620778; called by muse, mutect2, varscan2
- RGL1 | c.1408A>C p.M470L (on ENST00000360851 / NM_001297672.2; = p.M505L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/547 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58979611; called by muse, mutect2, varscan2
- RYR1 | c.11228A>G p.E3743G | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV62090578; called by muse, mutect2, varscan2
- S100A2 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 83/392 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV64184587; called by muse, mutect2, varscan2
- SAFB2 | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV53040909; called by muse, mutect2, varscan2
- SCYL3 | c.1696G>A p.E566K (on ENST00000367770; = p.E512K on NM_020423.7) | Missense Mutation (SNP) | VAF 127/678 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV53676997; called by muse, mutect2, varscan2
- SEC31B | c.2390C>G p.P797R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64843791; called by muse, mutect2, varscan2
- SIRPG | c.544T>C p.W182R | Missense Mutation (SNP) | VAF 97/631 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53806104; called by muse, mutect2, varscan2
- SLC44A2 | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs759275912, COSV59835333; called by muse, mutect2, varscan2
- TAS2R8 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV53688016; called by muse, mutect2, varscan2
- TMEM209 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61021701, COSV61023386; called by muse, mutect2, varscan2
- TP53 | c.420del p.C141Afs*29 | Frame Shift Del (DEL) | VAF 75/178 reads (42%) | catalogued as COSV52700425; called by mutect2, pindel, varscan2
- TRAPPC8 | c.4234T>C p.S1412P | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs775996748, COSV99350989; called by muse, mutect2
- TREM2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs761283027, COSV58293908; called by muse, mutect2, varscan2
- TTN | c.101756A>C p.K33919T (on ENST00000591111; = p.K26495T on NM_003319.4) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | PolyPhen benign (0.001); catalogued as COSV59909833; called by muse, mutect2, varscan2
- UNC5CL | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV55109123; called by muse, mutect2, varscan2
- USH2A | c.3775C>T p.L1259F | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56450454, COSV56453499; called by muse, mutect2, varscan2
- VPS9D1 | c.1388+1G>C p.X463_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV66993990; called by muse, mutect2, varscan2
- ZNF212 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1356630496, COSV100242334, COSV60025339; called by muse, mutect2, varscan2
- ZSCAN25 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500513; called by muse, mutect2
- ACAA1 | c.294_323+1del p.X98_splice | Splice Site (DEL) | VAF 3/42 reads (7%) | called by mutect2, pindel*
- ADORA3 | c.205_209delinsCATG p.A69Hfs*18 | Frame Shift Del (DEL) | VAF 39/162 reads (24%) | called by pindel, varscan2*
- FAM155B | c.1268del p.G423Afs*42 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- FCGBP | c.10371G>C p.Q3457H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.66); called by muse, mutect2
- IGKV1-5 | c.122T>A p.V41D | Missense Mutation (SNP) | VAF 162/311 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KLHDC9 | c.113dup p.R39Tfs*27 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- LCOR | c.3712C>G p.H1238D | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OGFOD1 | c.50del p.K17Rfs*6 | Frame Shift Del (DEL) | VAF 35/152 reads (23%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.8354_8356+8del p.X2785_splice | Splice Site (DEL) | VAF 20/44 reads (45%) | called by mutect2, pindel, varscan2
- USP53 | c.1062_1084del p.A355Qfs*19 | Frame Shift Del (DEL) | VAF 44/231 reads (19%) | called by mutect2, pindel
- ZFYVE27 | c.331_351del p.E111_L117del | In Frame Del (DEL) | VAF 28/231 reads (12%) | called by mutect2, pindel
- ARHGAP33 | c.1080G>A p.R360= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV99137920; called by muse, mutect2
- ATP1A4 | c.576G>A p.E192= | Silent (SNP) | VAF 95/315 reads (30%) | catalogued as rs1197355287, COSV63625630; called by muse, mutect2, varscan2
- CAMTA1 | c.4698T>A p.L1566= | Silent (SNP) | VAF 111/646 reads (17%) | catalogued as COSV57884293; called by muse, mutect2, varscan2
- CFH | c.2118C>A p.S706= | Silent (SNP) | VAF 166/505 reads (33%) | catalogued as COSV66405958, COSV66406188; called by muse, mutect2, varscan2
- DISP2 | c.3033G>A p.E1011= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs750789637, COSV51116996; called by muse, mutect2, varscan2
- EIF4G1 | c.2190A>G p.A730= (on ENST00000346169 / NM_198241.3; = p.A535= on NM_004953.5) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as rs1480370459, COSV59989383; called by muse, mutect2, varscan2
- ERCC3 | c.855C>T p.I285= | Silent (SNP) | VAF 54/281 reads (19%) | catalogued as COSV53425800; called by muse, mutect2, varscan2
- FLG | c.8541A>C p.S2847= | Silent (SNP) | VAF 140/2218 reads (6%) | catalogued as rs760968330, COSV100911448; called by muse, mutect2
- FMN2 | c.2763T>C p.P921= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs200259735, COSV60419232; called by muse, varscan2
- GRID1 | c.276G>A p.T92= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs370422959; called by muse, mutect2, varscan2
- KALRN | c.8400A>T p.A2800= (on ENST00000360013 / NM_001024660.4; = p.A1103= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV52250999; called by muse, mutect2, varscan2
- KMT2D | c.9078C>T p.G3026= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV56415336; called by muse, mutect2, varscan2
- MICU1 | c.1236G>C p.V412= (on ENST00000361114 / NM_001195518.2; = p.V418= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as rs545259526, COSV63143630; called by muse, mutect2, varscan2
- MROH1 | c.2868C>G p.V956= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- NOL3 | c.363G>T p.G121= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV50456661; called by muse, mutect2, varscan2
- PAG1 | c.714A>G p.Q238= | Silent (SNP) | VAF 33/267 reads (12%) | catalogued as COSV99597285; called by muse, mutect2, varscan2
- PIK3C2G | c.1602C>T p.N534= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV56798854; called by muse, mutect2, varscan2
- PKD1L1 | c.6261G>A p.K2087= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs1367035135, COSV56958967; called by muse, mutect2, varscan2
- SGCA | c.879C>A p.T293= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV56248571; called by muse, mutect2, varscan2
- SLC22A8 | c.312C>G p.T104= | Silent (SNP) | VAF 24/495 reads (5%) | catalogued as COSV100267829; called by muse, mutect2
- SMPDL3A | c.330T>C p.D110= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV63755149; called by muse, mutect2
- SORT1 | c.1452C>T p.A484= | Silent (SNP) | VAF 84/265 reads (32%) | catalogued as rs765501897, COSV56664530; called by muse, varscan2
- TIMM50 | c.807C>G p.G269= | Silent (SNP) | VAF 137/479 reads (29%) | catalogued as COSV58678877; called by muse, mutect2, varscan2
- ZPLD1 | c.861G>A p.Q287= (on ENST00000466937 / NM_001329788.1; = p.Q303= on NM_175056.2) | Silent (SNP) | VAF 123/389 reads (32%) | catalogued as COSV60352094; called by muse, mutect2, varscan2
- ZSCAN5A | c.699A>T p.P233= | Silent (SNP) | VAF 81/290 reads (28%) | catalogued as COSV54224376; called by muse, mutect2, varscan2
- ZZZ3 | c.2277T>C p.D759= | Silent (SNP) | VAF 77/359 reads (21%) | catalogued as COSV66231410; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445900 G>C | 3'Flank (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- IP6K1 | c.*1G>T | 3'UTR (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100389895; called by muse, mutect2, varscan2
